Somatic mutation profile of tumor specimen TARGET-10-PATRNA-09A (aliquot TARGET-10-PATRNA-09A-01D) from TARGET case TARGET-10-PATRNA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (803 days).
Specimen TARGET-10-PATRNA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fd2a483-074f-41bb-9594-263e21cb881f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATRNA-10A (Blood Derived Normal), aliquot TARGET-10-PATRNA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1c6a969-8d88-42b2-9bad-197f18bc18a3

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDHR4 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58526951; called by muse, mutect2
- HECTD4 | c.9664G>A p.D3222N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV66389719; called by muse, mutect2, varscan2
- KCNJ3 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV54534546; called by muse, mutect2, varscan2
- MYOM2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316996365, COSV50707353; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- PPRC1 | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV53384434; called by muse, mutect2, varscan2
- RSBN1L | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1040771251, COSV58507475; called by muse, mutect2, varscan2
- THSD7B | c.2759T>C p.L920P | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55672769; called by mutect2, varscan2
- CHAF1A | c.2488C>A p.Q830K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ERG | c.828G>T p.Q276H (on ENST00000398919 / NM_001243428.1; = p.Q252H on NM_004449.4) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.212); called by muse, mutect2
- HSF1 | c.753C>A p.S251R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.388); called by muse, mutect2
- IL18R1 | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- SOCS2 | c.-212C>A | Splice Region (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SYT16 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); called by muse, mutect2
- TRAJ61 | chr14:22475312 TGTGGGT>GGGTAA | Missense Mutation (DEL) | VAF 10/37 reads (27%) | called by pindel, varscan2*
- VRK2 | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); called by muse, mutect2
- DMP1 | c.1401C>T p.N467= | Silent (SNP) | VAF 41/304 reads (13%) | catalogued as rs1364914176; called by muse, mutect2, varscan2
- DNAH3 | c.3546G>T p.L1182= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- RPL3L | c.285C>A p.T95= | Silent (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- UBQLN1 | chr9:83712775 C>T | 5'Flank (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
